Somatic mutation profile of tumor specimen MP2PRT-PARGSC-TBP1-A (aliquot MP2PRT-PARGSC-TBP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PARGSC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 1.3 years (476 days).
Specimen MP2PRT-PARGSC-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57f59ed5-d4c8-44d0-84e2-898ab4e5eeb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARGSC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARGSC-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/472f18f3-8735-4506-abea-c6659c16a237

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 55/312 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PCDHA13 | c.2075C>T p.A692V | Missense Mutation (SNP) | VAF 72/389 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as rs368888498, COSV56545189; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3542T>G p.V1181G | Missense Mutation (SNP) | VAF 75/737 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- MROH2A | c.4294A>G p.K1432E | Missense Mutation (SNP) | VAF 64/514 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.47); called by muse, mutect2
- SPAG8 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 84/636 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
